CCDI case PBBVZV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/454327d2-0776-4e1a-80ca-4397575a2379

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 17.0 years (6,220 days).

Biospecimens (2 samples)
- Sample 0DITSE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DITT6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
